Somatic mutation profile of tumor specimen 0DWYWS from CCDI case PBCPAI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.9 years (4,704 days).
Specimen 0DWYWS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 220ca38d-3a8b-4f8a-8d3a-b65b12911a80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWYUP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b815cfe0-ef56-4025-b078-202889e42e3c

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as rs1388746108; called by muse, mutect2
- RNF227 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs1567886782; called by muse, mutect2, varscan2
- CHADL | c.679T>C p.S227P | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MKKS | c.1037G>A p.S346N | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, mutect2
- CCDC175 | c.126G>T p.A42= | Silent (SNP) | VAF 36/313 reads (12%) | catalogued as rs368882853; called by muse, mutect2, varscan2
- ACY1 | c.1002-71_1002-70del | Intron (DEL) | VAF 14/108 reads (13%) | called by mutect2, pindel, varscan2
